Somatic mutation profile of tumor specimen C3N-02067-01 (aliquot CPT0109830010) from CPTAC case C3N-02067, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 37.6 years (13,731 days).
Specimen C3N-02067-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a3afec6-ff87-47af-b8ed-2512e0b63aac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02067-71 (Blood Derived Normal), aliquot CPT0139390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ac57c8d-8ea8-41d4-bb10-8db4e6964383

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Intron 2, In Frame Del 1, 5'Flank 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD3 | c.3193+2T>C p.X1065_splice (on ENST00000297405 / NM_001363185.1; = p.X961_splice on NM_052900.3) | Splice Site (SNP) | VAF 30/375 reads (8%) | catalogued as rs887456759; called by muse, mutect2
- FAM47E-STBD1 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371047529; called by muse, mutect2
- OR2A42 | c.446C>A p.T149K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV101195851; called by mutect2, varscan2
- PCDHB16 | c.195G>C p.R65S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs782507416; called by muse, mutect2, varscan2
- PRIMPOL | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs372599218; called by muse, mutect2, varscan2
- SERPINB13 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs191405968, COSV54028622; called by muse, mutect2
- SPTA1 | c.456C>G p.D152E | Missense Mutation (SNP) | VAF 20/640 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1164094344; called by muse, mutect2
- TM6SF1 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs780558833, COSV51945964, COSV51946706; called by muse, mutect2
- TP53 | c.569dup p.P191Sfs*18 | Frame Shift Ins (INS) | VAF 180/525 reads (34%) | catalogued as COSV52939661; called by mutect2, pindel, varscan2
- ABCA7 | c.5350G>C p.V1784L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC008397.2 | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRA2 | c.719A>G p.D240G | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- BLZF1 | c.432A>C p.K144N | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- BRD2 | c.2315C>A p.S772* | Nonsense Mutation (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- CATSPER1 | c.1492A>C p.K498Q | Missense Mutation (SNP) | VAF 110/516 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CUL7 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 49/706 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2
- DYNC2H1 | c.10057G>C p.V3353L | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2
- FCHO2 | c.716T>G p.I239R | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GRIN3A | c.165G>T p.L55F | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2
- ITPRID1 | c.1996C>T p.H666Y | Missense Mutation (SNP) | VAF 72/470 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MAP4K4 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 8/227 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.664); called by muse, mutect2
- MAPK9 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- NUP160 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PAX3 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 21/318 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2
- PAX9 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.054); called by muse, mutect2
- PROM2 | c.1132_1140del p.A378_Q380del | In Frame Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel
- TAF1L | c.4721A>G p.K1574R | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.469); called by muse, mutect2
- TRMT1 | c.170T>G p.V57G | Missense Mutation (SNP) | VAF 25/438 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- ZFHX4 | c.2860C>A p.L954I | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CATSPERD | c.447T>C p.S149= | Silent (SNP) | VAF 53/187 reads (28%) | catalogued as COSV67534366; called by muse, mutect2, varscan2
- CD109 | c.4203G>T p.L1401= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV54649751; called by muse, mutect2
- DOCK3 | c.3237C>T p.S1079= | Silent (SNP) | VAF 19/161 reads (12%) | called by muse, mutect2, varscan2
- EEPD1 | c.1275G>A p.R425= | Silent (SNP) | VAF 71/246 reads (29%) | called by muse, mutect2, varscan2
- ITGAM | c.2829G>A p.T943= (on ENST00000648685 / NM_001145808.2; = p.T942= on NM_000632.4) | Silent (SNP) | VAF 25/454 reads (6%) | catalogued as rs1214682739; called by muse, mutect2
- PTPRH | c.3102C>T p.D1034= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as rs372963277, COSV54749458; called by muse, mutect2
- SMCR8 | c.126T>A p.A42= | Silent (SNP) | VAF 53/246 reads (22%) | called by muse, mutect2, varscan2
- SNX21 | c.519G>A p.S173= | Silent (SNP) | VAF 17/319 reads (5%) | catalogued as rs752760310, COSV54170699, COSV99467590; called by muse, mutect2
- ZNF454 | c.9C>T p.V3= | Silent (SNP) | VAF 8/161 reads (5%) | catalogued as COSV100194671, COSV100195181; called by muse, mutect2
- ELL | c.183+1852del | Intron (DEL) | VAF 24/232 reads (10%) | called by mutect2, pindel
- IK | chr5:140647663 A>G | 5'Flank (SNP) | VAF 42/584 reads (7%) | called by muse, mutect2
- RBM12B | c.-78+570T>C | Intron (SNP) | VAF 12/344 reads (3%) | called by muse, mutect2
